Somatic mutation profile of tumor specimen TCGA-AP-A05A-01A (aliquot TCGA-AP-A05A-01A-11W-A027-09) from TCGA case TCGA-AP-A05A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 81.9 years (29,914 days).
Specimen TCGA-AP-A05A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c536f05c-2cd4-46f6-8cc6-0220bfa41758.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A05A-10A (Blood Derived Normal), aliquot TCGA-AP-A05A-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e464b0f-6ca5-4d3c-87cd-8d60106ab655

The open-access MAF lists 80 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Nonsense Mutation 7, Splice Site 4, RNA 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 170/382 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 96/109 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSF2 | c.587A>G p.E196G | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV51973632; called by muse, mutect2, varscan2
- ACVR1B | c.1082A>G p.D361G | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV57779056; called by muse, mutect2, varscan2
- APOB | c.4702C>A p.L1568M | Missense Mutation (SNP) | VAF 119/386 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51921792; called by muse, mutect2, varscan2
- ARHGAP35 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 161/174 reads (93%) | catalogued as COSV68334058; called by muse, mutect2, varscan2
- ATAD2B | c.2444C>G p.S815* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as COSV53203250; called by muse, mutect2, varscan2
- ATXN7 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 176/395 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1283501933, COSV55754260; called by muse, mutect2, varscan2
- AWAT2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.428); catalogued as COSV52143033; called by muse, mutect2, varscan2
- BCL2L15 | c.167G>C p.R56P | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63643206; called by muse, mutect2, varscan2
- BIRC6 | c.9772G>T p.V3258F | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV70203614; called by muse, mutect2, varscan2
- CARD6 | c.2281C>A p.Q761K | Missense Mutation (SNP) | VAF 20/659 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV54567913; called by muse, mutect2
- CCT2 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 230/377 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54741043; called by muse, mutect2, varscan2
- CEP350 | c.3656C>A p.S1219Y | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV62600529, COSV62607329; called by mutect2, varscan2
- CHD4 | c.2868G>C p.K956N (on ENST00000357008 / NM_001363606.2; = p.K969N on NM_001273.5) | Missense Mutation (SNP) | VAF 240/414 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58907441; called by muse, mutect2, varscan2
- COL16A1 | c.1228A>C p.K410Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.627); catalogued as COSV54711164; called by muse, mutect2, varscan2
- CSMD3 | c.9380G>T p.R3127L (on ENST00000297405 / NM_001363185.1; = p.R2958L on NM_052900.3) | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.932); catalogued as rs752773200, COSV52165293, COSV52249136; called by muse, mutect2, varscan2
- CSMD3 | c.742T>A p.S248T | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.197); catalogued as COSV52263554; called by muse, mutect2, varscan2
- DPYD | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 76/150 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs72549306, CM983497, COSV64608823; called by muse, mutect2, varscan2
- EXOSC10 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as COSV58666924; called by muse, mutect2, varscan2
- FAM160B1 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 128/255 reads (50%) | catalogued as COSV65089072; called by muse, mutect2, varscan2
- FATE1 | c.221G>C p.R74P | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as rs759629114, COSV64848903, COSV64849200; called by muse, mutect2, varscan2
- FNDC1 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 173/422 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51944301; called by muse, mutect2, varscan2
- GRIK2 | c.2515G>C p.V839L | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV59757096; called by muse, mutect2, varscan2
- GTF3C1 | c.3151+2T>A p.X1051_splice | Splice Site (SNP) | VAF 44/100 reads (44%) | catalogued as COSV62243434; called by muse, mutect2, varscan2
- HEPH | c.912C>A p.H304Q (on ENST00000343002; = p.H37Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57968944; called by muse, mutect2, varscan2
- IGKV1-5 | c.250T>G p.F84V | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750220908; called by muse, mutect2
- LIPC | c.1051+2T>A p.X351_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as COSV54425700; called by muse, mutect2, varscan2
- LRRC20 | c.545C>A p.P182H (on ENST00000355790 / NM_207119.3; = p.P126H on NM_018205.4) | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as COSV62938890; called by mutect2, varscan2
- LTBP4 | c.2489G>C p.G830A (on ENST00000308370 / NM_001042544.1; = p.G793A on NM_003573.2) | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.878); catalogued as COSV52587216; called by muse, mutect2, varscan2
- MCRS1 | c.1003+1G>T p.X335_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | catalogued as COSV57790899, COSV57792073; called by muse, mutect2, varscan2
- MTOR | c.7322G>A p.R2441Q | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.207); catalogued as rs1413993125, COSV63875719; called by muse, mutect2
- MUC20 | c.2085C>G p.H695Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV57853066; called by muse, mutect2, varscan2
- NOLC1 | c.337G>C p.G113R | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as rs373288971, COSV100893518, COSV100893669, COSV64180855; called by muse, mutect2, varscan2
- NOTCH4 | c.5933G>T p.R1978L | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV66681440, COSV66683101; called by muse, mutect2, varscan2
- NPHP3 | c.2298G>C p.E766D | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV58632221; called by muse, mutect2, varscan2
- OTOF | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs956438436, COSV55512415; called by muse, mutect2, varscan2
- PCSK2 | c.976A>G p.M326V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV52739416; called by muse, mutect2, varscan2
- PEX5L | c.761C>G p.A254G | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV55852274; called by muse, mutect2, varscan2
- PLCE1 | c.133A>G p.R45G | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV53363567; called by muse, mutect2, varscan2
- POLQ | c.6049C>A p.L2017I | Missense Mutation (SNP) | VAF 76/211 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51757909; called by muse, mutect2, varscan2
- PRKAB1 | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV57555392; called by muse, mutect2, varscan2
- PTPRJ | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 61/130 reads (47%) | catalogued as COSV69253618; called by muse, mutect2, varscan2
- PUM1 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 169/519 reads (33%) | catalogued as COSV57089208, COSV57090401; called by muse, mutect2, varscan2
- RNF214 | c.1235G>C p.R412P | Missense Mutation (SNP) | VAF 104/217 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV56117997, COSV56120300; called by muse, mutect2, varscan2
- SCIN | c.1882A>T p.I628F (on ENST00000297029 / NM_001112706.3; = p.I381F on NM_033128.3) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV51696503; called by muse, mutect2, varscan2
- SERTAD4 | c.981T>G p.N327K | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV65399861; called by muse, mutect2, varscan2
- SLC22A25 | c.504C>A p.D168E | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60597873; called by muse, mutect2, varscan2
- STOX2 | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV57854677; called by muse, mutect2, varscan2
- SYVN1 | c.88T>A p.Y30N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53696621; called by muse, mutect2, varscan2
- TEX11 | c.949T>C p.S317P (on ENST00000344304; = p.S302P on NM_031276.3) | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs1027601995, COSV60235565; called by muse, mutect2, varscan2
- TEX14 | c.1788G>C p.E596D (on ENST00000240361 / NM_001201457.2; = p.E590D on NM_031272.5) | Missense Mutation (SNP) | VAF 57/77 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV53622767; called by muse, mutect2, varscan2
- UGCG | c.1138T>A p.Y380N | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV65336291; called by muse, mutect2, varscan2
- USP33 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs751948861, COSV62468442; called by muse, mutect2, varscan2
- UTRN | c.5032A>C p.I1678L | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.729); catalogued as COSV62342764; called by muse, mutect2, varscan2
- VCAN | c.1407T>A p.Y469* | Nonsense Mutation (SNP) | VAF 141/290 reads (49%) | catalogued as COSV54095600, COSV54112439; called by muse, mutect2, varscan2
- ZNF592 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV55438598; called by muse, mutect2
- ZNF99 | c.2300G>T p.G767V | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68056222; called by muse, mutect2, varscan2
- ABCA7 | c.5005C>T p.L1669F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- MAGT1 | c.405_409del p.A136Nfs*15 (on ENST00000618282 / NM_001367916.1; = p.A168Nfs*15 on NM_032121.5) | Frame Shift Del (DEL) | VAF 61/155 reads (39%) | called by mutect2, pindel, varscan2
- MSH2 | c.1276+1_1276+10del p.X426_splice | Splice Site (DEL) | VAF 25/147 reads (17%) | called by mutect2, pindel, varscan2
- ANKRD52 | c.3147C>T p.C1049= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs750404672, COSV57286256; called by muse, mutect2
- AOC1 | c.798G>A p.P266= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs370158924, COSV62867404; called by muse, mutect2, varscan2
- COL10A1 | c.918G>A p.L306= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV54573960; called by muse, mutect2, varscan2
- CYB5R4 | c.462C>T p.S154= | Silent (SNP) | VAF 63/156 reads (40%) | catalogued as rs62419732, COSV63751633; called by muse, mutect2, varscan2
- DNAJC15 | c.177G>A p.R59= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as rs1396370377, COSV64872808; called by muse, mutect2, varscan2
- GRIN2A | c.75G>A p.A25= | Silent (SNP) | VAF 21/34 reads (62%) | catalogued as COSV58048872; called by muse, mutect2, varscan2
- MAP3K5 | c.1770C>T p.H590= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs770224799, COSV62889787; called by muse, mutect2, varscan2
- MYH11 | c.5139G>A p.L1713= | Silent (SNP) | VAF 58/119 reads (49%) | catalogued as COSV55563476; called by muse, mutect2, varscan2
- MYRF | c.897C>T p.P299= (on ENST00000278836 / NM_001127392.3; = p.P290= on NM_013279.4) | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as rs779832183, COSV53891986, COSV99607683; called by muse, mutect2, varscan2
- RAI14 | c.2067C>T p.N689= | Silent (SNP) | VAF 74/202 reads (37%) | catalogued as rs768901243, COSV54294916; called by muse, mutect2, varscan2
- RING1 | c.501A>C p.T167= | Silent (SNP) | VAF 114/289 reads (39%) | catalogued as COSV63002813; called by muse, mutect2, varscan2
- STXBP3 | c.1404T>C p.T468= | Silent (SNP) | VAF 156/339 reads (46%) | catalogued as COSV64183108; called by muse, mutect2, varscan2
- SYTL3 | c.45C>G p.R15= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV51913396; called by muse, mutect2, varscan2
- TPR | c.774G>A p.L258= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV66603620; called by muse, mutect2, varscan2
- USP19 | c.639G>T p.P213= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV59736180; called by muse, mutect2, varscan2
- ZNF431 | c.495C>T p.N165= | Silent (SNP) | VAF 81/244 reads (33%) | catalogued as COSV60674550; called by muse, mutect2, varscan2
- SLMAP | c.1135+6932C>G | Intron (SNP) | VAF 39/102 reads (38%) | catalogued as COSV55851050; called by muse, mutect2, varscan2
- SNORD114-25 | n.50G>A | RNA (SNP) | VAF 173/341 reads (51%) | catalogued as rs762253283; called by muse, mutect2, varscan2
- SSPOP | n.6814A>G | RNA (SNP) | VAF 13/36 reads (36%) | catalogued as COSV50488682; called by muse, mutect2, varscan2
